Surgical pathology report (de-identified scan), TCGA case TCGA-W4-A7U2, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of North Carolina, specimen TCGA-W4-A7U2-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

Left testicle, left radical orchiectomy -

Tumor histologic type: Mixed germ cell tumor (seminoma 50%,
mature teratoma 45%, embryonal carcinoma 5%)

Tumor size: 5.5 cm

Tumor focality: Unifocal

Extent of invasion:

Epididymis: Not involved

Tunica vaginalis: Not involved

Spermatic cord: Not involved

Paratesticular soft tissues: Not involved

Rete testis: Not involved

Lymphatics: Not involved

Surgical margins, including spermatic cord margin: Negative

Other significant findings: None

AJCC Stage: pT1 pNx pMx

This staging information is based on this pathologic specimen
and may be incomplete. A comprehensive review of all available
information is recommended to determine final staging.

Clinical History:

year-old male with left testicular mass. Scrotal ultrasound
demonstrated mixed cystic and solid testicular mass.

Labs: AFP 15 (ULN 10), beta HCG <5.

Gross Description:

Specimen fixation: formalin

Type/side of specimen: left radical orchiectomy

Size of specimen: Testicle, 6.7 x 3.9 x 5.7 cm; 99.2 grams

[page 2 of 3]
Structures attached to testis: epididymis, spermatic cord and vaginalis; The spermatic cord is 9.8 x 1.9 cm (diameter).

Orientation: The tunica vaginalis was inked blue. This retracted during fixation.

Tumor description: heterogeneous mass effacing almost the entire testicle parenchyma except for a small rim; the mass has lobulated tan/white areas with focal hemorrhage and a subjacent cystic and solid mass with areas of firmness and possible calcification

Tumor size: 5.7 x 3.3 x 3.7 cm

Focality of tumor: unifocal

Confinement/non-confinement:

Tunica albuginea: abutting the tunica albuginea, but does appear to be confined

Relationship of tumor to adjacent anatomic structures:

Epididymis: does not grossly involve

Tunica vaginalis: does not grossly involve

Paratesticular soft tissues: does not grossly involve

Spermatic cord: does not grossly involve

Distance of tumor from surgical margins: 9.0 cm from the distal spermatic cord margin

Description of remainder of tissue: The inferior pole at the testicle has a small zone of grossly normal testicular parenchyma; the rest of the testicle is effaced by tumor. The cystic and solid mass predominates the upper pole of the kidney.

Tissue submitted for special investigation: yes; Tissue Procurement

Digital photograph taken: no

Block Summary:

[page 3 of 3]
- A1 - spermatic cord margin
- A2 - proximal spermatic cord
- A3 - tunica vaginalis
- A4 - tumor in relation to epididymis
- A5 - solid white/tan lobulated mass to cystic mass
- A6,A7 - additional sections of mass in relation to tunica albuginea
- A8 - mass in relation to grossly normal lower pole testicular tissue
- A9 - solid mass in relation to grossly normal testicular tissue
- A10 - mass in relation to epididymis
- A11 - mass in relation to rete testis
- A12 - additional random sections of testicular mass

Grossing Pathologist:

Light Microscopy:

Light microscopic examination is performed by Dr. No immature teratoma is noted. Slide A11 shows a 1.8cm focus of undifferentiated carcinoma, AFP(-), CD30(-), interpreted as embryonal carcinoma. Dr. concurs.

Dual/Synchronous Primary	NOTED	

Source: NCI Genomic Data Commons file 970ce9b7-196f-404a-b5a3-b8f5a026a861 (TCGA-W4-A7U2.1A357BEF-5E0A-4810-BAA9-F968DB7A898D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).